Somatic mutation profile of tumor specimen TCGA-NJ-A55O-01A (aliquot TCGA-NJ-A55O-01A-11D-A25L-08) from TCGA case TCGA-NJ-A55O, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 56.5 years (20,628 days).
Specimen TCGA-NJ-A55O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7eeb9de9-ec08-41f3-8450-f8701c736fd2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NJ-A55O-10A (Blood Derived Normal), aliquot TCGA-NJ-A55O-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18b98442-0ada-44e7-a357-fd772524de60

The open-access MAF lists 150 somatic variants for this specimen: 117 protein-altering or splice-affecting, 30 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 101, Silent 30, Nonsense Mutation 11, Splice Site 2, Frame Shift Del 2, RNA 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC4 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.044); catalogued as rs200696756; called by muse, mutect2, varscan2
- ACOX3 | c.1004A>T p.Q335L | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs762266346, COSV100712046; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4941G>T p.W1647C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV99720927; called by muse, mutect2, varscan2
- ADCK1 | c.759G>T p.W253C | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99452567; called by muse, mutect2
- ANKRD30A | c.2521G>T p.D841Y (on ENST00000611781; = p.D785Y on NM_052997.2) | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV100654373, COSV64605221; called by muse, mutect2, varscan2
- ANO4 | c.1080G>T p.M360I (on ENST00000392977 / NM_001286615.2; = p.M325I on NM_178826.4) | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as rs761199298, COSV99041061; called by muse, mutect2, varscan2
- APOB | c.9953C>A p.P3318Q | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99267707; called by muse, mutect2, varscan2
- AQR | c.2128G>T p.A710S | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV99334600; called by muse, mutect2
- ARHGEF4 | c.16C>A p.P6T | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); catalogued as COSV100388619; called by muse, mutect2, varscan2
- ATP7A | c.1727C>A p.A576D | Missense Mutation (SNP) | VAF 24/424 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100431616; called by muse, mutect2
- ATR | c.4049C>A p.A1350D | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV100638555; called by muse, mutect2
- BRINP3 | c.1347C>A p.C449* | Nonsense Mutation (SNP) | VAF 9/92 reads (10%) | catalogued as COSV66522749; called by muse, mutect2, varscan2
- BTK | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100437884; called by muse, mutect2, varscan2
- CCL1 | c.97T>A p.C33S | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99861840; called by muse, mutect2
- CDH6 | c.1915C>A p.Q639K | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.803); catalogued as COSV99420678; called by muse, mutect2, varscan2
- CDH7 | c.2168G>T p.G723V | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV100543144, COSV59896951; called by muse, mutect2, varscan2
- CDON | c.2647G>T p.E883* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as COSV99701931; called by muse, mutect2, varscan2
- CIDEB | c.581T>A p.L194Q | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99351131; called by muse, mutect2
- CNKSR2 | c.1640C>A p.S547* | Nonsense Mutation (SNP) | VAF 5/54 reads (9%) | catalogued as COSV99667858; called by muse, mutect2, varscan2
- CNTNAP2 | c.1394C>A p.A465D | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100671469; called by muse, mutect2, varscan2
- CNTNAP4 | c.2211C>A p.C737* | Nonsense Mutation (SNP) | VAF 11/200 reads (6%) | catalogued as COSV56673736; called by muse, mutect2
- COL21A1 | c.1939G>T p.G647C | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99780066; called by muse, mutect2, varscan2
- CPD | c.3724A>G p.T1242A | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.954); catalogued as COSV99853223; called by muse, mutect2, varscan2
- CUX1 | c.83A>T p.E28V (on ENST00000292535 / NM_181552.4; = p.E39V on NM_001913.5) | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99472918; called by muse, mutect2
- DEFB118 | c.56C>G p.P19R | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV104388010; called by muse, mutect2
- DNAH10 | c.3020A>T p.Q1007L (on ENST00000409039; = p.Q946L on NM_207437.3) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as COSV101292620; called by muse, mutect2, varscan2
- DNAJB8 | c.434T>A p.M145K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0.161); catalogued as COSV100048477; called by muse, mutect2, varscan2
- DSC3 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100844707; called by muse, mutect2
- EEF1AKMT3 | c.292G>T p.G98W | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100103762; called by muse, mutect2, varscan2
- EPN2 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs1370170938, COSV59061125; called by muse, mutect2
- FAT3 | c.4070C>A p.P1357H | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV99970550; called by muse, mutect2
- FAT4 | c.12176G>C p.G4059A | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100630001, COSV58708575; called by muse, mutect2, varscan2
- GALNT14 | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.053); catalogued as rs149431826; called by muse, mutect2
- GALNT7 | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.057); catalogued as COSV99397768; called by muse, mutect2, varscan2
- GLP2R | c.560C>A p.S187Y | Missense Mutation (SNP) | VAF 26/374 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.856); catalogued as COSV99302420; called by muse, mutect2
- GNL3L | c.1491G>C p.Q497H | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as rs1178401197, COSV100328583; called by muse, mutect2, varscan2
- GPR158 | c.2072G>A p.R691Q | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs140090961, COSV66269203, COSV66273719; called by muse, mutect2, varscan2
- GPR50 | c.1420C>A p.P474T | Missense Mutation (SNP) | VAF 31/485 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.185); catalogued as COSV99506219; called by muse, mutect2
- GRIA3 | c.1627G>T p.G543C | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99991601; called by muse, mutect2
- GRIA3 | c.1628G>T p.G543V | Missense Mutation (SNP) | VAF 20/324 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99991605; called by muse, mutect2
- HECTD4 | c.3763A>T p.S1255C | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100296202; called by muse, mutect2, varscan2
- HERC3 | c.2507+1G>T p.X836_splice | Splice Site (SNP) | VAF 18/93 reads (19%) | catalogued as COSV52020505; called by muse, mutect2, varscan2
- HFM1 | c.2687C>T p.S896L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.406); catalogued as COSV99646708; called by muse, mutect2, varscan2
- IGFN1 | c.2297C>A p.A766E (on ENST00000295591 / NM_001367841.1; = p.A3223E on NM_001164586.2) | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as COSV55170542, COSV99813487; called by muse, mutect2
- IRF6 | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV100884028; called by muse, mutect2, varscan2
- KCNB1 | c.1233C>G p.I411M | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100870586, COSV65566016, COSV65569625; called by muse, mutect2, varscan2
- KCND2 | c.327C>A p.H109Q | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100478320, COSV58567402; called by muse, mutect2, varscan2
- KIAA0232 | c.1261G>T p.E421* | Nonsense Mutation (SNP) | VAF 9/85 reads (11%) | catalogued as COSV100301081; called by muse, mutect2, varscan2
- KLHL3 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100553526; called by muse, mutect2
- KRT19 | c.797A>G p.D266G | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54177933, COSV99563258; called by muse, mutect2
- LIM2 | c.131G>C p.R44P | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99702464; called by muse, mutect2, varscan2
- MAGEA4 | c.73C>A p.L25M | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99367694; called by muse, mutect2
- MAGEE1 | c.1743G>C p.M581I | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); catalogued as COSV100819511; called by muse, mutect2, varscan2
- MSL3 | c.200C>A p.A67E | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100385049; called by muse, mutect2
- MUC16 | c.29128C>A p.P9710T | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.327); catalogued as COSV67453496; called by muse, mutect2, varscan2
- MUC16 | c.9650G>T p.S3217I | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV101201408; called by muse, mutect2, varscan2
- MYH9 | c.2639C>A p.A880E | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99339745; called by muse, mutect2, varscan2
- NARS2 | c.1165-1G>T p.X389_splice | Splice Site (SNP) | VAF 3/42 reads (7%) | catalogued as rs1202312854, COSV55255989; called by muse, mutect2
- NCSTN | c.582G>T p.Q194H | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99667584; called by muse, mutect2, varscan2
- NGLY1 | c.1212G>T p.K404N | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV99770896; called by muse, mutect2, varscan2
- NLRP2 | c.2508A>T p.R836S | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.313); catalogued as COSV99672613; called by muse, mutect2, varscan2
- OPTC | c.850C>A p.Q284K | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as COSV100921832; called by muse, mutect2
- OR13C8 | c.447G>T p.W149C | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100623018; called by muse, mutect2, varscan2
- OR2G6 | c.282C>A p.Y94* | Nonsense Mutation (SNP) | VAF 11/149 reads (7%) | catalogued as COSV100598123, COSV100598307; called by muse, mutect2
- OR2L2 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 34/268 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.292); catalogued as COSV100824315; called by muse, mutect2, varscan2
- OR5AS1 | c.386C>G p.P129R | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100546369; called by muse, mutect2
- OR6K3 | c.288G>C p.K96N (on ENST00000368146; = p.K80N on NM_001005327.2) | Missense Mutation (SNP) | VAF 30/283 reads (11%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.924); catalogued as COSV100933868, COSV100933887; called by muse, mutect2, varscan2
- OR8H2 | c.805G>T p.G269* | Nonsense Mutation (SNP) | VAF 17/155 reads (11%) | catalogued as COSV100542469; called by muse, mutect2, varscan2
- OSM | c.109G>T p.V37L | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV53161104, COSV99304315; called by muse, mutect2
- PCDH11X | c.1321G>T p.A441S | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.145); catalogued as COSV100014769; called by muse, mutect2
- PCF11 | c.2204G>C p.G735A | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as COSV53537777; called by muse, mutect2, varscan2
- PLCB4 | c.884A>T p.Y295F | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.047); catalogued as COSV99596807; called by muse, mutect2, varscan2
- PLCH1 | c.1816G>T p.V606L (on ENST00000340059 / NM_001130960.2; = p.V618L on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as COSV100398124; called by muse, mutect2
- PRLR | c.547C>A p.H183N | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.736); catalogued as COSV99184219; called by muse, mutect2, varscan2
- RAB41 | c.199G>C p.D67H (on ENST00000374473 / NM_001363807.1; = p.D66H on NM_001032726.3) | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99333837; called by muse, mutect2
- RASGRP4 | c.272G>T p.W91L | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV99498808; called by muse, mutect2, varscan2
- RPAP1 | c.2717A>T p.Q906L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100427321; called by mutect2, varscan2
- SACM1L | c.1231C>T p.Q411* | Nonsense Mutation (SNP) | VAF 5/93 reads (5%) | catalogued as COSV101203792; called by muse, mutect2
- SEC63 | c.1190G>T p.R397L | Missense Mutation (SNP) | VAF 11/201 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as COSV100938469; called by muse, mutect2
- SERPINB12 | c.1106A>T p.E369V | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV99501896; called by muse, mutect2, varscan2
- SF3B1 | c.2324G>T p.R775L | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV59206813, COSV59209777; called by muse, mutect2, varscan2
- SIM1 | c.1250C>A p.P417Q | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as COSV99492728; called by muse, mutect2, varscan2
- SIPA1L2 | c.647G>T p.R216L | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs780265795, COSV53395898, COSV99479538; called by muse, mutect2, varscan2
- SLC6A5 | c.2171G>T p.C724F | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV100117117; called by muse, mutect2, varscan2
- SLCO2B1 | c.1838C>A p.P613H | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56939847, COSV99215155; called by muse, mutect2, varscan2
- SPTA1 | c.3079C>G p.P1027A | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100935508, COSV63748584; called by muse, mutect2, varscan2
- SPTA1 | c.1724G>T p.R575L | Missense Mutation (SNP) | VAF 24/313 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100935510, COSV63748678; called by muse, mutect2
- STK11 | c.206C>A p.S69* | Nonsense Mutation (SNP) | VAF 3/28 reads (11%) | catalogued as COSV100479841, COSV58822317; called by muse, mutect2
- TANC1 | c.2396C>T p.S799F | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99713538, COSV99715071; called by muse, mutect2, varscan2
- TAS1R2 | c.1531C>A p.H511N | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV100946357; called by muse, mutect2, varscan2
- TBC1D12 | c.1744A>T p.R582W | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99831768; called by muse, mutect2, varscan2
- TIAM1 | c.4543G>T p.V1515L | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99733859; called by muse, mutect2, varscan2
- TLR2 | c.469G>T p.G157* | Nonsense Mutation (SNP) | VAF 8/118 reads (7%) | catalogued as COSV99472521; called by muse, mutect2
- TM9SF4 | c.1837G>A p.V613I | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.105); catalogued as COSV54107278, COSV99455095; called by muse, mutect2, varscan2
- TRIM3 | c.1718G>A p.G573D | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100624531; called by muse, mutect2, varscan2
- TRIML1 | c.1349C>A p.P450Q | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV100206285, COSV60196839; called by muse, mutect2
- TRIOBP | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.356); catalogued as rs139454337, COSV100731096; called by mutect2, varscan2
- TRPV6 | c.1385G>T p.G462V | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100844418; called by muse, mutect2
- TST | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs1335416020, COSV99968246; called by muse, mutect2
- USP26 | c.2603C>G p.A868G | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.842); catalogued as COSV100896750; called by muse, mutect2
- VCAM1 | c.719G>T p.G240V | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV99658888; called by muse, mutect2
- VCAN | c.8564G>T p.G2855V | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs1047377743, COSV99427163; called by muse, mutect2, varscan2
- VPS13C | c.2171A>G p.N724S (on ENST00000644861 / NM_020821.3; = p.N681S on NM_017684.5) | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.028); catalogued as rs143708476; called by muse, mutect2
- WDR83OS | c.119T>A p.L40Q | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99664010; called by muse, mutect2
- ZCWPW1 | c.706C>T p.H236Y | Missense Mutation (SNP) | VAF 19/217 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100228410; called by muse, mutect2
- ZNF546 | c.901T>C p.Y301H | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.896); catalogued as COSV100713548; called by muse, mutect2
- ZNF566 | c.7C>T p.Q3* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as COSV67574730; called by muse, mutect2, varscan2
- CLASP1 | c.1557A>T p.R519S | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.527); called by muse, mutect2
- COL6A3 | c.1506dup p.P503Sfs*32 | Frame Shift Ins (INS) | VAF 20/170 reads (12%) | called by mutect2, pindel, varscan2
- MMP20 | c.832G>T p.G278W | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); called by mutect2, varscan2
- NLRP2 | c.929A>G p.K310R | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.226); called by muse, mutect2
- NOX3 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHB5 | c.707del p.N236Mfs*25 | Frame Shift Del (DEL) | VAF 42/314 reads (13%) | called by mutect2, pindel, varscan2
- PCDHB9 | c.691G>A p.V231M | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.192); called by muse, mutect2
- SACS | c.10409C>A p.P3470H | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); called by muse, mutect2
- TICRR | c.891del p.S298Rfs*27 | Frame Shift Del (DEL) | VAF 20/127 reads (16%) | called by mutect2, pindel, varscan2
- ADAMTS18 | c.621A>T p.A207= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV99273998; called by muse, mutect2, varscan2
- BRWD3 | c.5370A>G p.E1790= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV100956475; called by muse, mutect2, varscan2
- EIF4G3 | c.768A>T p.I256= | Silent (SNP) | VAF 13/144 reads (9%) | catalogued as COSV99945474; called by muse, mutect2
- FAM47B | c.216C>A p.R72= | Silent (SNP) | VAF 5/102 reads (5%) | catalogued as COSV100264588; called by muse, mutect2
- FAT2 | c.1017C>T p.S339= | Silent (SNP) | VAF 42/237 reads (18%) | catalogued as rs368178113; called by muse, mutect2, varscan2
- FCGR2C | c.195T>A p.S65= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV100913107; called by muse, mutect2
- GYPC | c.381T>C p.F127= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs1246756447, COSV99392045; called by muse, mutect2, varscan2
- INSC | c.429C>A p.A143= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs921727981, COSV101089632; called by muse, mutect2
- INSRR | c.1677G>T p.G559= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV100948029; called by muse, mutect2, varscan2
- LRRC8B | c.219G>A p.L73= | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as COSV100446674; called by muse, mutect2
- MSL3 | c.201A>G p.A67= | Silent (SNP) | VAF 8/136 reads (6%) | catalogued as COSV100385052; called by muse, mutect2
- MUC16 | c.35751C>A p.S11917= | Silent (SNP) | VAF 10/131 reads (8%) | catalogued as COSV101198450, COSV101201407; called by muse, mutect2
- MYL10 | c.420G>T p.T140= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV99781161; called by muse, mutect2, varscan2
- NENF | c.249A>T p.G83= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100877098; called by muse, mutect2
- NTNG1 | c.816G>A p.G272= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV53982436; called by muse, mutect2, varscan2
- OR13C4 | c.432G>T p.L144= | Silent (SNP) | VAF 14/180 reads (8%) | catalogued as COSV99470287; called by muse, mutect2
- OR14K1 | c.531C>T p.C177= | Silent (SNP) | VAF 26/277 reads (9%) | catalogued as rs766726383, COSV99315448; called by muse, mutect2
- OR4S2 | c.477T>A p.A159= | Silent (SNP) | VAF 55/370 reads (15%) | catalogued as COSV100412785; called by muse, mutect2, varscan2
- PCDHB8 | c.1422C>A p.V474= | Silent (SNP) | VAF 38/522 reads (7%) | catalogued as COSV99177321; called by muse, mutect2
- RLF | c.591A>C p.P197= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV101035675; called by muse, mutect2, varscan2
- ROBO4 | c.999T>A p.P333= | Silent (SNP) | VAF 9/113 reads (8%) | catalogued as COSV100127846; called by muse, mutect2
- RYR3 | c.1407C>A p.L469= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV101214266; called by muse, mutect2, varscan2
- SLITRK2 | c.2535G>C p.L845= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as COSV100158162; called by muse, mutect2
- SMARCA1 | c.2806C>T p.L936= | Silent (SNP) | VAF 14/224 reads (6%) | catalogued as COSV100946699; called by muse, mutect2
- TIMM8A | c.15C>T p.S5= | Silent (SNP) | VAF 6/130 reads (5%) | catalogued as rs369736736, COSV100437883; ClinVar: likely benign / benign; called by muse, mutect2
- TMEM176A | c.396C>T p.A132= | Silent (SNP) | VAF 18/124 reads (15%) | catalogued as COSV99133982; called by muse, mutect2, varscan2
- TMPRSS4 | c.564G>T p.L188= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as COSV101449426; called by muse, mutect2, varscan2
- ZNF154 | c.222C>A p.A74= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV101377543; called by muse, mutect2, varscan2
- ZNF566 | c.6T>C p.A2= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs778544535, COSV101091577; called by muse, mutect2, varscan2
- ZNF592 | c.2499C>T p.P833= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs1349896263, COSV100246102; called by muse, mutect2, varscan2
- CEP128 | c.1209+902G>T | Intron (SNP) | VAF 3/9 reads (33%) | catalogued as COSV99383644; called by muse, mutect2
- MIR519A2 | n.25G>A | RNA (SNP) | VAF 26/203 reads (13%) | called by muse, mutect2, varscan2
- SNORD116-24 | n.74C>A | RNA (SNP) | VAF 29/238 reads (12%) | called by muse, mutect2, varscan2
